Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A7GX, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A7GX-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site @ Kidney NOS C64.9
9/24/13

Surgical Pathology Report

Diagnosis:

Kidney, right, laparoscopic radical nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, chromophobe subtype, eosinophilic variant

Sarcomatoid features: not identified

Histologic grade (if applicable): 2 (of 4, Fuhrman classification)

Tumor size (greatest dimension): 7.2 cm

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Extra-capsular invasion into perirenal adipose tissue: not identified

Gerota's fascia: n/a

Renal sinus: not involved

Major veins (renal vein or segmental branches, IVC): not involved

Ureter: not involved

Lymphatics: not involved

Surgical margins:

Extracapsular soft tissue margin: not involved

Renal vein margin: not involved

Ureter margin: not involved

Adrenal gland: not received

Lymph nodes: none received

Other significant findings: none

AJCC Stage: pT2a pNx pMx

Clinical History:

70 male with right renal mass.

[page 2 of 2]
Gross Description:

Received is one appropriately labeled container, additionally labeled "right kidney." It consists of a radical nephrectomy specimen (17.1 x 7.7 x 6.8 cm) consisting of kidney (14.6 x 7.2 x 4.7 cm, 427 gram). The upper pole has a 7.2 x 7.2 x 7.0 cm well circumscribed soft, pink/tan solid mass with focal hemorrhage and necrosis (20%). The mass expands the capsule, does not go through it, and is 0.4 cm from the perinephric adipose tissue margin (inked blue). The mass is 1.5 cm from the renal sinus. The renal vein is free of mass. The uninvolved cortex medulla is well demarcated, red/brown without additional masses. No hilar lymph node candidates are identified. Adrenal gland is absent.

Block summary:

- A1 - ureter, renal vein and artery margins, en face
- A2 - renal sinus (perpendicular)
- A3,A4 - perpendicular of mass closest to the perinephric adipose tissue margin
- A5-A7 - additional sections of mass
- A8 - normal kidney from inferior pole

Light Microscopy:

Light microscopic examination is performed by Dr.

Sections show irregular nests of eosinophilic cells with punched out perinuclear clearing. By H & E alone, the differential diagnosis includes eosinophilic variant of chromophobe carcinoma, as well as granular variant of clear cell carcinoma. To clarify lineage, immunostains and Hale's colloidal iron stain were performed, and show reactivity for CK7 and Hale's colloidal iron, with no reactivity for RCC. The immunophenotype supports the above diagnosis.

Source: NCI Genomic Data Commons file 2936fb2e-5456-49e2-8ffd-2d67d36706af (TCGA-UW-A7GX.F489FC43-C5D4-42F0-8397-A115A9ACDB89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).